Somatic mutation profile of tumor specimen TCGA-C5-A907-01A (aliquot TCGA-C5-A907-01A-11D-A37N-09) from TCGA case TCGA-C5-A907, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G2; Age at diagnosis: 47.4 years (17,304 days).
Specimen TCGA-C5-A907-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9805931-6127-42f8-a4ca-5f6a7484e73b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A907-10A (Blood Derived Normal), aliquot TCGA-C5-A907-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/087667e4-fccf-4367-adc1-8d04fe3cfde3

The open-access MAF lists 51 somatic variants for this specimen: 42 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 8, Nonsense Mutation 4, Frame Shift Del 2, Intron 1, Splice Site 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACR | c.541G>A p.G181S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376947740; called by mutect2, varscan2
- ADAMTSL1 | c.2821G>A p.D941N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101002107; called by muse, mutect2, varscan2
- ATP5F1B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.38); catalogued as COSV100008246; called by muse, mutect2, varscan2
- ATP8B4 | c.2443G>A p.D815N | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99465440; called by muse, varscan2
- ATP8B4 | c.2308G>A p.D770N | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.02); catalogued as rs755699504, COSV99467967; called by mutect2, varscan2
- BRPF3 | c.2063C>T p.A688V | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.996); catalogued as COSV60206171; called by muse, mutect2
- CCDC144A | c.278T>G p.V93G | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); catalogued as COSV100502262; called by muse, mutect2, varscan2
- CCDC39 | c.1852G>A p.D618N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV99869015, COSV99870886; called by muse, mutect2, varscan2
- CKAP5 | c.3628G>C p.D1210H | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV100371581; called by muse, mutect2, varscan2
- CLOCK | c.677C>G p.S226C | Missense Mutation (SNP) | VAF 32/48 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs199554011, COSV100012074; called by muse, mutect2, varscan2
- COL18A1 | c.2851C>T p.L951F (on ENST00000359759 / NM_130444.3; = p.L716F on NM_030582.4) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.114); catalogued as COSV100700998; called by muse, mutect2, varscan2
- GPR82 | c.522C>G p.Y174* | Nonsense Mutation (SNP) | VAF 20/58 reads (34%) | catalogued as COSV100220705; called by muse, mutect2, varscan2
- HERC2 | c.7798G>C p.D2600H | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99877456; called by muse, mutect2, varscan2
- KMT2C | c.1290G>A p.W430* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as COSV100077752, COSV51438161; called by muse, mutect2, varscan2
- KMT2C | c.1289G>A p.W430* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as COSV100076359, COSV100077754; called by muse, mutect2, varscan2
- LAMA1 | c.8290G>A p.A2764T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs781696472, COSV101057971; called by muse, mutect2, varscan2
- LAMC1 | c.4543A>G p.S1515G | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99280637; called by muse, mutect2, varscan2
- LRIT1 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.648); catalogued as rs750253759, COSV64512047; called by muse, mutect2, varscan2
- MTIF2 | c.890C>G p.P297R | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99709405; called by muse, mutect2, varscan2
- NFAT5 | c.4475C>G p.S1492C | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV100591331; called by muse, mutect2, varscan2
- NLRP8 | c.264G>C p.L88F | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99406102; called by muse, mutect2, varscan2
- PCDH19 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99721007; called by muse, mutect2, varscan2
- PCDHA12 | c.1979C>T p.T660M | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.223); catalogued as rs782361627, COSV56539774; called by muse, mutect2, varscan2
- PIGK | c.892G>A p.V298I | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as COSV100769971; called by muse, mutect2, varscan2
- PRKDC | c.11712del p.F3904Lfs*7 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as COSV58062662; called by mutect2, pindel, varscan2
- PRKG2 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV100020686; called by muse, mutect2, varscan2
- PSAPL1 | c.811G>A p.G271R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.035); catalogued as rs549020477, COSV100040780, COSV59844584; called by muse, mutect2, varscan2
- RAPGEF5 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100688035; called by muse, mutect2, varscan2
- SH3PXD2A | c.2758G>A p.E920K (on ENST00000369774 / NM_001365079.1; = p.E892K on NM_014631.2) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.955); catalogued as rs371255618, COSV100280568; called by muse, mutect2
- SHQ1 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs200718937, COSV100345441; called by muse, mutect2, varscan2
- SLC4A4 | c.1799C>T p.A600V (on ENST00000264485 / NM_001098484.3; = p.A556V on NM_003759.4) | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99143282; called by muse, mutect2, varscan2
- SP2 | c.1477G>C p.E493Q | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV100947311; called by muse, varscan2
- SRPRA | c.953G>A p.G318D | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as COSV99703182; called by muse, mutect2, varscan2
- TNS1 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1159381184, COSV99412173; called by muse, mutect2, varscan2
- UGT2B4 | c.1329G>A p.M443I | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV59317739, COSV59320467; called by muse, mutect2, varscan2
- UNC13B | c.315G>T p.M105I | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV101037489; called by muse, mutect2, varscan2
- VASP | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs571015875, COSV55606956; called by muse, mutect2, varscan2
- XDH | c.1367A>G p.Y456C | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs765594300, COSV101052505; called by muse, mutect2, varscan2
- ZGRF1 | c.5485G>C p.E1829Q | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV101500691; called by muse, mutect2, varscan2
- ZNF576 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs1334556616, COSV60671023; called by muse, mutect2, varscan2
- ADAM30 | c.329del p.C110Sfs*7 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | called by mutect2, pindel, varscan2
- MRC1 | c.4078+1del p.X1360_splice | Splice Site (DEL) | VAF 21/98 reads (21%) | called by mutect2, pindel, varscan2
- ASB12 | c.549C>T p.G183= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs767310102, COSV100744853, COSV100744888; called by muse, mutect2, varscan2
- B3GNT3 | c.318G>A p.P106= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as rs1460255893; called by muse, mutect2
- CLOCK | c.678C>T p.S226= | Silent (SNP) | VAF 31/48 reads (65%) | catalogued as rs554766108, COSV100012071; called by muse, mutect2, varscan2
- MYOF | c.3507C>T p.L1169= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100826204, COSV63710065; called by muse, mutect2, varscan2
- PSMD2 | c.798G>A p.L266= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100032046; called by muse, mutect2, varscan2
- TCHH | c.2463C>G p.R821= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100915580; called by muse, mutect2, varscan2
- TLN2 | c.1761G>A p.L587= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100170297; called by muse, mutect2, varscan2
- ZNF532 | c.1083C>A p.V361= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV100267293, COSV60175658; called by muse, mutect2, varscan2
- RAPH1 | c.732+12468del | Intron (DEL) | VAF 15/45 reads (33%) | catalogued as COSV100051275; called by mutect2, pindel, varscan2
